Somatic mutation profile of tumor specimen TCGA-B9-A5W8-01A (aliquot TCGA-B9-A5W8-01A-11D-A28G-10) from TCGA case TCGA-B9-A5W8, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 50.5 years (18,440 days).
Specimen TCGA-B9-A5W8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cf4e5d9-9063-4ee4-8d9a-16b88434b156.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-A5W8-10A (Blood Derived Normal), aliquot TCGA-B9-A5W8-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb696879-f2dc-4f4a-82cd-2c9f4ffb98fb

The open-access MAF lists 53 somatic variants for this specimen: 33 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 18, Missense Mutation 18, Frame Shift Del 3, In Frame Del 3, Nonstop Mutation 2, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 2, In Frame Ins 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSF2 | c.1139-2A>G p.X380_splice | Splice Site (SNP) | VAF 41/119 reads (34%) | catalogued as COSV51972025; called by muse, mutect2, varscan2
- APBB2 | c.2276A>T p.*759Lext*15 (on ENST00000295974 / NM_001166050.2; = p.*760Lext*15 on NM_004307.2) | Nonstop Mutation (SNP) | VAF 21/94 reads (22%) | catalogued as COSV55951030; called by muse, mutect2, varscan2
- ARMCX5 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55766362; called by muse, mutect2
- BBS7 | c.734A>T p.D245V | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV52655830; called by muse, mutect2, varscan2
- CCDC186 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV65159440; called by mutect2, varscan2
- CD163L1 | c.3646C>A p.H1216N | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.569); catalogued as COSV100549798, COSV58014547; called by muse, mutect2, varscan2
- CDR2 | c.848T>C p.F283S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as COSV51675970; called by muse, mutect2, varscan2
- DHX34 | c.539T>C p.V180A | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60895111; called by muse, mutect2, varscan2
- DTNBP1 | c.923G>C p.R308P | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV59039397; called by muse, mutect2, varscan2
- ENPP1 | c.391A>C p.N131H | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62931780; called by muse, mutect2, varscan2
- GGT5 | c.489C>G p.F163L | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV54069678, COSV54071971; called by muse, mutect2, varscan2
- GIGYF2 | c.572G>C p.G191A | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.371); catalogued as COSV101004334, COSV65248456; called by muse, mutect2, varscan2
- GLYATL2 | c.872A>G p.K291R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1435200926, COSV54849686; called by muse, mutect2, varscan2
- GOLIM4 | c.1490A>G p.Q497R | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.814); catalogued as COSV58329285; called by muse, mutect2
- H3C12 | c.55A>C p.K19Q | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); catalogued as COSV58152461; called by muse, mutect2, varscan2
- MAML2 | c.1817_1818insACA p.Q621dup | In Frame Ins (INS) | VAF 11/81 reads (14%) | catalogued as rs771061219; called by pindel, varscan2
- METAP2 | c.1195A>G p.T399A | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51563399; called by mutect2, varscan2
- MICALL2 | c.2123-1G>C p.X708_splice | Splice Site (SNP) | VAF 33/142 reads (23%) | catalogued as COSV52515340; called by muse, mutect2, varscan2
- NFAT5 | c.3796C>T p.Q1266* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as COSV63026700; called by muse, mutect2, varscan2
- NUP210 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV54405219; called by muse, mutect2, varscan2
- PBX1 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as COSV61533478; called by muse, mutect2, varscan2
- PIP5K1B | c.563T>C p.M188T | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55245913; called by muse, varscan2
- SH3KBP1 | c.1890delinsTA p.Q630Hfs*6 | Frame Shift Ins (INS) | VAF 43/102 reads (42%) | catalogued as COSV65648700; called by pindel, varscan2*
- SLC38A4 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.172); catalogued as rs768636628, COSV56966741; called by muse, mutect2, varscan2
- SUSD4 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.432); catalogued as COSV59551931; called by muse, mutect2, varscan2
- H2AC16 | c.227_229del p.K76del | In Frame Del (DEL) | VAF 38/184 reads (21%) | called by pindel, varscan2
- KMT2C | c.11165del p.K3722Rfs*23 | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | called by mutect2, pindel, varscan2
- METTL7A | c.190_210del p.E64_G70del | In Frame Del (DEL) | VAF 16/82 reads (20%) | called by mutect2, pindel, varscan2
- NEUROD1 | c.537_540del p.T180Pfs*81 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
- RFC5 | c.432del p.K144Nfs*34 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | called by mutect2, pindel, varscan2
- TCEANC | c.180_182del p.S61del (on ENST00000380600 / NM_001297563.2; = p.S91del on NM_152634.4) | In Frame Del (DEL) | VAF 28/52 reads (54%) | called by mutect2, pindel, varscan2
- TMCC3 | c.406dup p.Y136Lfs*15 | Frame Shift Ins (INS) | VAF 10/69 reads (14%) | called by mutect2, pindel, varscan2
- ZNF225 | c.2109_*1delinsTT | Nonstop Mutation (DEL) | VAF 17/93 reads (18%) | called by pindel, varscan2*
- ACOT13 | c.330A>T p.G110= | Silent (SNP) | VAF 8/212 reads (4%) | catalogued as COSV57764178; called by muse, mutect2
- ACTRT2 | c.591C>A p.L197= | Silent (SNP) | VAF 63/168 reads (38%) | catalogued as COSV65759196; called by muse, mutect2, varscan2
- CBLL1 | c.489C>T p.L163= | Silent (SNP) | VAF 30/139 reads (22%) | catalogued as rs780892517, COSV56028668; called by muse, mutect2, varscan2
- CD163L1 | c.3645G>A p.T1215= | Silent (SNP) | VAF 41/257 reads (16%) | catalogued as rs368002565; called by muse, mutect2, varscan2
- DNAJB9 | c.117G>A p.E39= | Silent (SNP) | VAF 41/130 reads (32%) | catalogued as rs767268558, COSV50812055; called by muse, mutect2, varscan2
- EVC | c.1275G>A p.Q425= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV53831647; called by muse, mutect2, varscan2
- FRYL | c.6621T>C p.S2207= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV51944900; called by muse, mutect2, varscan2
- GABRA6 | c.312T>C p.N104= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV50879768; called by muse, mutect2, varscan2
- KIAA0232 | c.462G>A p.E154= | Silent (SNP) | VAF 78/258 reads (30%) | catalogued as rs981071614, COSV56924645; called by muse, varscan2
- MAML2 | c.1800G>A p.Q600= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as rs1454381988; called by muse, varscan2
- MTHFSD | c.948C>T p.D316= (on ENST00000360900 / NM_001159377.2; = p.D315= on NM_022764.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as rs753102249, COSV59802832; called by muse, mutect2, varscan2
- PDLIM4 | c.300C>T p.H100= | Silent (SNP) | VAF 66/217 reads (30%) | catalogued as rs774647839, COSV53803839; called by muse, mutect2, varscan2
- RBM5 | c.1335T>C p.P445= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as COSV61737261; called by muse, mutect2, varscan2
- SLC22A4 | c.492A>C p.S164= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV52357814, COSV52360241; called by muse, mutect2, varscan2
- TAF1 | c.3660G>A p.K1220= (on ENST00000373790 / NM_138923.4; = p.K1241= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/118 reads (58%) | catalogued as COSV52111429; called by muse, mutect2, varscan2
- TIFAB | c.315C>G p.V105= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as COSV72345725, COSV72345774; called by muse, mutect2, varscan2
- XPOT | c.102C>A p.A34= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV60344879; called by muse, mutect2, varscan2
- ZNF629 | c.1224C>T p.G408= | Silent (SNP) | VAF 47/166 reads (28%) | catalogued as COSV52698129; called by muse, mutect2, varscan2
- OSGIN1 | n.958G>A | RNA (SNP) | VAF 55/166 reads (33%) | catalogued as COSV59675220; called by muse, mutect2, varscan2
- R3HDML | chr20:44355829 G>T | 3'Flank (SNP) | VAF 14/63 reads (22%) | catalogued as rs769394388, COSV53835695; called by muse, mutect2, varscan2
